Gene-level copy-number profile of tumor specimen ALCH-ADC3-TTP1-A from ALCHEMIST case ALCH-ADC3, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.8 years (26,209 days).
Specimen ALCH-ADC3-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6759acdf-e895-4018-9a38-8991650d281c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADC3-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/dd0350eb-9a52-46fd-ae52-d004b1d7a504

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 72; copy number 1: 3,052; copy number 2: 55,730; copy number 3: 54; copy number 6: 3.

Homozygous deletions (total copy number 0; autosomes only): 59 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:91,578,478–91,621,421, 3 genes (within-gene range 0–1): AC233266.1, AC233266.2, AC116050.1.
- chr7:63,567,743–63,621,169, 2 genes: TNRC18P2, MIR4283-2.
- chr7:63,768,257–63,771,047, 1 gene: CICP24.
- chr7:129,770,383–129,785,185, 4 genes: MIR182, MIR96, MIR183, AC084864.1.
- chr14:100,537,147–100,587,413, 2 genes: BEGAIN, AL845552.2.
- chr15:25,169,337–25,249,279, 44 genes (within-gene range 0–2): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43.
- chr22:18,773,665–18,843,399, 3 genes (within-gene range 0–4): GGT3P, AC008132.2, E2F6P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:143,761,790–143,836,933, 3 genes, copy number 6 (within-gene range 3–6): AC099548.2, PAICSP6, AC099548.1.

Autosomal genes at a single copy (total copy number 1): 214. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
